Somatic mutation profile of tumor specimen 4ccb249a-6722-491e-97e9-e3b4e7 (aliquot 4ccb249a-6722-491e-97e9-e3b4e7_D6) from CPTAC case 04OV013, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 4ccb249a-6722-491e-97e9-e3b4e7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a48b3334-56ac-45de-bd1e-c661bdeca90d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 9c2d08e0-9dc3-4aec-95bb-b75855 (Blood Derived Normal), aliquot 9c2d08e0-9dc3-4aec-95bb-b75855_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f14f0cb-f998-4f8f-ae8f-4819f393006d

The open-access MAF lists 141 somatic variants for this specimen: 95 protein-altering or splice-affecting, 33 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 33, Frame Shift Del 7, Nonsense Mutation 6, 3'UTR 5, Intron 4, RNA 3, Splice Site 3, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.7360C>T p.R2454C | Missense Mutation (SNP) | VAF 102/700 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs193922816, CM992215; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 241/394 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3303G>T p.W1101C | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011257; called by mutect2, varscan2
- ASPM | c.8905A>G p.R2969G | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV54129004; called by muse, mutect2, varscan2
- CNGB3 | c.96C>A p.H32Q | Missense Mutation (SNP) | VAF 140/641 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60686315; called by mutect2, varscan2
- DNAH11 | c.8117A>G p.Y2706C | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs1060503066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPC5 | c.279C>A p.S93R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65584965; called by muse, mutect2, varscan2
- GUCY2D | c.3128C>T p.T1043M | Missense Mutation (SNP) | VAF 71/658 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104369010; called by muse, mutect2, varscan2
- IFT172 | c.3676G>C p.A1226P | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53138077; called by muse, mutect2, varscan2
- MSI1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs149956156; called by muse, mutect2
- MTA1 | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1555434099, COSV100231763; called by muse, mutect2, varscan2
- NAT10 | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs766037793; called by muse, mutect2, varscan2
- NPAS4 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758872170; called by muse, mutect2, varscan2
- PLXND1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441551728; called by muse, mutect2, varscan2
- PRPF4B | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs1392508084; called by muse, mutect2
- PTPRT | c.3589G>T p.G1197W | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62008804, COSV62011673; called by muse, mutect2, varscan2
- SDR16C5 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58128010; called by muse, mutect2, varscan2
- SLC29A1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506007; called by muse, mutect2, varscan2
- UBR3 | c.3799C>A p.R1267S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99774235; called by muse, mutect2, varscan2
- ZNF184 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as rs866935240, COSV53004188; called by muse, mutect2, varscan2
- ZNF93 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs750407862; called by muse, mutect2, varscan2
- ABCA2 | c.1884C>A p.Y628* (on ENST00000614293; = p.Y598* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- ACO1 | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL3 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD52 | c.3036_3040dup p.I1014Tfs*2 | Nonsense Mutation (INS) | VAF 86/303 reads (28%) | called by mutect2, pindel, varscan2
- APOB | c.11767T>A p.F3923I | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ARHGEF17 | c.3203A>G p.K1068R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ARID1A | c.5836G>C p.A1946P | Missense Mutation (SNP) | VAF 177/375 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL13B | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- ASPM | c.5070G>C p.K1690N | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- AVPR1A | c.372_381del p.C124* | Frame Shift Del (DEL) | VAF 125/504 reads (25%) | called by mutect2, pindel, varscan2
- BRSK1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- C16orf95 | c.*41-4C>G | Splice Region (SNP) | VAF 30/206 reads (15%) | called by mutect2, varscan2
- CD163L1 | c.2477T>C p.L826P | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300C | c.114_145del p.L39Qfs*17 | Frame Shift Del (DEL) | VAF 40/390 reads (10%) | called by mutect2, pindel
- CDH15 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 87/510 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH16 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5RAP2 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 196/626 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIDO1 | c.6470G>A p.R2157H | Missense Mutation (SNP) | VAF 101/450 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DPH2 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FAM13A | c.1781C>G p.A594G | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FAM204A | c.589A>C p.K197Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FER1L6 | c.905_909del p.P302Lfs*3 | Frame Shift Del (DEL) | VAF 29/169 reads (17%) | called by mutect2, pindel, varscan2
- FN1 | c.1948T>C p.S650P | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, varscan2
- GADD45B | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAL3ST1 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GZMB | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HID1 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HPN | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYAL4 | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IFT52 | c.114T>G p.I38M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- KCNH7 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LAMC1 | c.1137T>A p.C379* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- LNX1 | c.431C>G p.S144* (on ENST00000263925 / NM_001126328.3; = p.S48* on NM_032622.2) | Nonsense Mutation (SNP) | VAF 43/241 reads (18%) | called by muse, mutect2, varscan2
- LRCH4 | c.1773_1776+11del p.X591_splice | Splice Site (DEL) | VAF 21/132 reads (16%) | called by mutect2, pindel*, varscan2*
- LRP1B | c.7097A>C p.N2366T | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAFK | c.195_223del p.A66Efs*21 | Frame Shift Del (DEL) | VAF 69/465 reads (15%) | called by mutect2, pindel, varscan2
- MCC | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 61/366 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MRC2 | c.2112C>A p.C704* | Nonsense Mutation (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- NSD2 | c.2520G>T p.G840= | Splice Region (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- NWD2 | c.2536A>G p.K846E | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR2A14 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- PDZD2 | c.7870G>C p.V2624L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PER1 | c.529+2T>C p.X177_splice | Splice Site (SNP) | VAF 33/293 reads (11%) | called by muse, mutect2, varscan2
- PER1 | c.285_286del p.Q96Efs*31 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by pindel, varscan2
- PLCL2 | c.3254T>C p.L1085P (on ENST00000615277 / NM_001144382.2; = p.L959P on NM_015184.5) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PRSS37 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- QARS1 | c.2222T>G p.F741C | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RADIL | c.80T>G p.M27R | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RGS22 | c.2261C>A p.P754Q | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RGS4 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- SBF2 | c.5469dup p.V1824Cfs*3 | Frame Shift Ins (INS) | VAF 48/327 reads (15%) | called by mutect2, pindel, varscan2
- SELENBP1 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2
- SERPINI2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); called by muse, mutect2
- SH2D3C | c.1955_1980del p.L652Pfs*96 (on ENST00000314830 / NM_170600.3; = p.L495Pfs*96 on NM_005489.4) | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel, varscan2
- SIAE | c.889A>T p.I297F | Missense Mutation (SNP) | VAF 85/644 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SLAMF7 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SMCHD1 | c.1774A>C p.K592Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMYD1 | c.992del p.L331Yfs*24 | Frame Shift Del (DEL) | VAF 56/185 reads (30%) | called by mutect2, pindel, varscan2
- SNX15 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SPTA1 | c.7204A>T p.S2402C | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TDRD9 | c.2389A>T p.R797* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- TMEM65 | c.516-2del p.X172_splice | Splice Site (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- TNFAIP8L3 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TNFRSF6B | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRAF3 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 96/523 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- TRAPPC13 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRERF1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- TTYH2 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- YEATS2 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2
- ZBTB4 | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF225 | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ZNF541 | c.3515T>A p.L1172H | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF573 | c.1525T>G p.L509V (on ENST00000536220 / NM_001172692.1; = p.L451V on NM_152360.3) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ZSCAN10 | c.62C>A p.A21D (on ENST00000252463; = p.A76D on NM_032805.3) | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ABCA7 | c.4104G>A p.P1368= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as rs555514637, COSV99565572; called by muse, mutect2, varscan2
- ABL2 | c.1503A>C p.G501= (on ENST00000502732 / NM_007314.4; = p.G486= on NM_005158.5) | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- ACAD8 | c.1221G>C p.L407= | Silent (SNP) | VAF 170/354 reads (48%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1326C>G p.T442= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- ANKRD44 | c.963G>A p.R321= | Silent (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
- CAGE1 | c.525A>G p.T175= (on ENST00000512086; = p.T39= on NM_205864.3) | Silent (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- CDC42BPB | c.2538C>T p.L846= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as rs759161809; called by muse, mutect2, varscan2
- CHD8 | c.3492C>T p.I1164= (on ENST00000646647 / NM_001170629.2; = p.I885= on NM_020920.4) | Silent (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- DTL | c.888C>T p.Y296= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as rs1187015745; called by muse, mutect2
- DYRK1A | c.234G>A p.Q78= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- FBN1 | c.4446C>T p.G1482= | Silent (SNP) | VAF 86/305 reads (28%) | catalogued as rs772727859, COSV57316746; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMD8 | c.648C>A p.L216= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- GRID2IP | c.1776C>G p.P592= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs1343069346; called by muse, mutect2, varscan2
- HABP2 | c.705T>C p.A235= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- HPN | c.1134C>G p.G378= | Silent (SNP) | VAF 122/266 reads (46%) | called by mutect2, varscan2
- IMMP2L | c.45T>C p.F15= | Silent (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- LINGO2 | c.150C>A p.A50= | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- LTBP3 | c.2010C>T p.C670= | Silent (SNP) | VAF 52/303 reads (17%) | catalogued as rs1393547117, COSV57238707; called by muse, mutect2, varscan2
- NAT16 | c.630G>A p.P210= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs1427704545; called by muse, mutect2
- NTRK3 | c.1050G>T p.V350= | Silent (SNP) | VAF 128/566 reads (23%) | called by mutect2, varscan2
- PCNX2 | c.2307G>A p.Q769= | Silent (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2
- PHC3 | c.2907A>G p.P969= (on ENST00000494943 / NM_001308116.2; = p.P981= on NM_024947.4) | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PI4KA | c.1410G>T p.T470= | Silent (SNP) | VAF 96/218 reads (44%) | called by muse, mutect2, varscan2
- POP1 | c.498C>T p.A166= | Silent (SNP) | VAF 31/261 reads (12%) | catalogued as rs748460495, COSV62892175; called by muse, mutect2, varscan2
- PPP1R3G | c.666C>A p.R222= | Silent (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- PRR32 | c.219C>G p.P73= | Silent (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- PTPRE | c.915A>T p.G305= | Silent (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- RNH1 | c.51C>T p.D17= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as rs776115867; called by muse, mutect2, varscan2
- SAMHD1 | c.438C>T p.Y146= | Silent (SNP) | VAF 88/359 reads (25%) | called by muse, mutect2, varscan2
- SLC12A1 | c.2622T>G p.P874= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- SNX15 | c.615C>T p.G205= | Silent (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- ST6GALNAC6 | c.381G>A p.E127= | Silent (SNP) | VAF 44/249 reads (18%) | catalogued as rs144348873; called by muse, mutect2, varscan2
- TCF15 | c.264G>A p.V88= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- AC092718.9 | chr16:81148157 G>C | 5'Flank (SNP) | VAF 43/242 reads (18%) | called by muse, mutect2, varscan2
- APOL4 | c.45-10C>G | Intron (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- CLCA4 | c.1467+56A>G | Intron (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- DCST2 | c.805+60G>T | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- DNASE1L2 | c.*1C>A | 3'UTR (SNP) | VAF 50/399 reads (13%) | called by muse, mutect2, varscan2
- DUSP13 | c.*144G>T | 3'UTR (SNP) | VAF 82/280 reads (29%) | called by muse, mutect2, varscan2
- IRAK1 | c.*834A>G | 3'UTR (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- KRT85 | c.*42C>A | 3'UTR (SNP) | VAF 30/274 reads (11%) | catalogued as COSV57737606; called by muse, varscan2
- KRT85 | c.*41G>A | 3'UTR (SNP) | VAF 30/274 reads (11%) | catalogued as rs899935737; called by muse, varscan2
- LIG3 | c.2796+230_2796+232del | Intron (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- OR2M1P | n.646G>A | RNA (SNP) | VAF 193/1044 reads (18%) | catalogued as rs767757397; called by muse, mutect2, varscan2
- SNORD114-3 | n.7A>T | RNA (SNP) | VAF 14/153 reads (9%) | called by muse, mutect2
- Vault | n.94A>G | RNA (SNP) | VAF 25/98 reads (26%) | catalogued as rs780492117; called by muse, mutect2, varscan2
